TCGA case TCGA-2F-A9KO — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd3a6357-9087-44b2-9956-f981e0de6f1c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 63 years; Vital status: Dead; Days to death: 734 days (2.0 years).

Diagnoses (5)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.4; Tissue or organ of origin: Posterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 63.9 years (23,323 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 734 days (2.0 years).
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 1; Lymph nodes tested: 18; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Lymph node, NOS. Age at diagnosis: 65.6 years (23,974 days); Days to diagnosis: 651 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Age at diagnosis: 65.6 years (23,974 days); Days to diagnosis: 651 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Liver. Age at diagnosis: 65.6 years (23,974 days); Days to diagnosis: 651 days (1.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Adrenal gland, NOS. Age at diagnosis: 65.6 years (23,974 days); Days to diagnosis: 651 days (1.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (7 entries)
- Day 651 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 651 days (1.8 years).
- Day 651 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 651 days (1.8 years).
- Day 651 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 651 days (1.8 years).
- Day 651 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to progression: 651 days (1.8 years).
- Days to follow up: 678 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 734 days (2.0 years); Disease response: With Tumor.
- Karnofsky performance status: 80.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 173 cm; BMI: 21.7.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 69; Age at onset: 20.
- Occupation duration years: 36; Occupation type: Machinery Mechanics and Repairers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2F-A9KO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 160 mg.
  Slide TCGA-2F-A9KO-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2F-A9KO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2F-A9KO-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 3,800 mg.
  Slide TCGA-2F-A9KO-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: unemployed; Occupation primary: mechanical fitter; Occupation primary industry: construction; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form 1: Lost to follow-up: Yes; Tumor status: With tumor.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 734 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 734 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 651 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2F-A9KO-01A-11D-A38F-01): tumor purity 0.36, ploidy 2.85, whole-genome doublings 1.
